Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6703, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6703-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Formatted Path Report		
		ID
[REDACTED]	[REDACTED]	[REDACTED]
LARGE INTESTINE TISSUE CHECKLIST		
Specimen type: Partial colectomy		
Specimen size: Not specified		
Tumor site: Ascending colon		
Tumor size: 0 x 0 x 8.5 cm		
Tumor features: Ulcerated		
Histologic type: Adenocarcinoma		
Histologic grade: Moderately differentiated		
Tumor extent: Subserosa		
Lymph nodes: 0/12 positive for metastasis (Adjacent fatty tissue 0/12)		
Margins: Uninvolved		
Evidence of neo-adjuvant treatment: Not specified		
Additional pathologic findings: Not specified		
Comments: None		

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 7fa445f5-59fe-43a2-a73e-95880b0acb4c (TCGA-F4-6703.227ED987-C3D7-420F-9276-2F803646323B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).